Somatic mutation profile of tumor specimen TCGA-AB-2804-03B (aliquot TCGA-AB-2804-03B-01W-0728-08) from TCGA case TCGA-AB-2804, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, t(15;17)(q22;q11-12); Tissue or organ of origin: Bone marrow; Age at diagnosis: 30.7 years (11,203 days).
Specimen TCGA-AB-2804-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe3a94c1-79ba-460f-bb9a-c424c10d7429.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2804-11B (Solid Tissue Normal), aliquot TCGA-AB-2804-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49957ae9-c88f-46f4-a6fd-8bf7d2db07d1

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 3, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A2 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 172/545 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV58044724; called by muse, varscan2
- GNRHR | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325732095, CM066865, COSV56933216, COSV56933808; called by muse, mutect2, varscan2
- LILRB2 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs771636990, COSV58745760; called by muse, mutect2, varscan2
- LIMS2 | c.290C>G p.P97R (on ENST00000355119 / NM_001161403.3; = p.P121R on NM_017980.4) | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1512099, COSV55754983, COSV55755471; called by muse, mutect2, varscan2
- NEIL1 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as rs778081651, COSV51227717; called by muse, mutect2, varscan2
- OTOA | c.2279C>T p.T760M (on ENST00000286149; = p.T746M on NM_144672.4) | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.12); catalogued as rs768161528, COSV53753464; called by muse, mutect2, varscan2
- PCDH1 | c.2545C>T p.Q849* | Nonsense Mutation (SNP) | VAF 34/1168 reads (3%) | catalogued as COSV99745711; called by muse, mutect2
- PHF6 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 59/82 reads (72%) | catalogued as COSV59701107, COSV59701200; called by muse, mutect2, varscan2
- MRC1 | c.947G>A p.C316Y | Missense Mutation (SNP) | VAF 25/637 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PLP1 | c.387A>T p.Q129H | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2
- SLAMF9 | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by mutect2, varscan2
- SCML2 | c.1764C>T p.D588= | Silent (SNP) | VAF 90/117 reads (77%) | catalogued as COSV52621616; called by muse, mutect2, varscan2
- SOGA3 | c.2172C>T p.Y724= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs979165424, COSV64106047; called by muse, mutect2, varscan2
- NIPAL3 | c.774-1108T>C | Intron (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
